Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A1L1, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A1L1-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Gastric & Mixed Tumo
Account #: [REDACTED] Date of Procedure:
DOB: [REDACTED] Date of Receipt:
Physician: [REDACTED]
CC: [REDACTED]

....

Specimens Submitted:

- 1: SP: Pelvic and left retroperitoneal sarcoma
- 2: SP: Left kidney
- 3: SP: Iliac vein

DIAGNOSIS:

- 1) SOFT TISSUE, PELVIC AND LEFT RETROPERITONEAL SARCOMA, SEGMENT OF COLON; RESECTION:
- DEDIFFERENTIATED LIPOSARCOMA.
- THE DEDIFFERENTIATED COMPONENT PREDOMINATES AND HAS A HIGH GRADE MYXOFIBROSARCOMA-LIKE GROWTH PATTERN.
- THE TUMOR IS PRESENT AS TWO MASSES MEASURING 8.5 X 7.5 X 3.5 CM AND 3.5 X 3.2 X 2.6 CM, RESPECTIVELY.
- THE TUMOR INVOLVES PERICOLONIC SOFT TISSUES AND FOCALLY INFILTRATES INTO THE BOWEL WALL.
- FOCAL TUMOR NECROSIS IS IDENTIFIED.
- TWO BENIGN LYMPH NODES (0/2).
- THE BOWEL, URETER, AND VASCULAR MARGINS ARE FREE OF TUMOR.
- GROSSLY, THE TUMOR IS COVERED BY A THIN TRANSLUCENT MEMBRANE, AND MICROSCOPICALLY THE TUMOR IS PRESENT LESS THAN 1.0 MM FROM THE INKED SOFT TISSUE MARGIN.
- 2) LEFT KIDNEY AND ADRENAL GLAND, LEFT NEPHRECTOMY:
- KIDNEY WITH FOCAL CAPSULAR FIBROSIS, NO TUMOR SEEN (SEE NOTE).
- ADRENAL GLAND WITH NO SIGNIFICANT HISTOPATHOLOGICAL DIAGNOSIS.
- THE URETER, VASCULAR, AND SOFT TISSUE MARGINS ARE BENIGN.

NOTE: THE CAPSULE OF THE KIDNEY IS FOCALLY THICKENED, GROSSLY. MICROSCOPIC EXAMINATION OF THESE AREAS REVEALED SCATTERED ATYPICAL STROMAL CELLS WHICH ARE IMMUNOHISTOCHEMICALLY NEGATIVE FOR MDM2, CDK4 AND HMB-45. THESE FINDINGS ARE CONSISTENT WITH A REACTIVE RATHER THAN NEOPLASTIC PROCESS.

- 3) ILIAC VEIN; EXCISION:
- FRAGMENTS OF DEDIFFERENTIATED LIPOSARCOMA INVOLVING FIBROADIPOSE TISSUE.
- THE VEIN IS FREE OF TUMOR.

** Continued on next page **

ICD-0-3

*Dedifferentiated liposarcoma 8858/3
Site retroperitoneum C48.0*

2/21/11

hr

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: Gastric & Mixed Tumo

Page 2 of 4

- ONE BENIGN LYMPH NODE (0/1).

NOTE: SLIDES FROM THE PATIENT'S PRIOR BIOPSY HAVE BEEN REVIEWED.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh and is labeled "pelvic and left retroperitoneal sarcoma". It consists of an unoriented, unopened segment of colon that measures 21.2 cm in length and 6.5 cm in greatest circumference. The external surface is remarkable for two adherent multi-nodular, white-yellow fleshy masses measuring 8.5 x 7.5 x 3.5 cm and 3.5 x 3.2 x 2.6 cm respectively which are located 4.2 cm from one bowel margin (designated margin one), 8.5 cm from the other bowel margin (designated margin two), 0.5 cm from the closest ureter margin, and 0.4 cm from the vascular margins. These masses are centered within the subserosal fibroadipose tissue and do not grossly extend into the bowel wall. The cut surfaces of the masses are heterogeneous with areas appearing soft and gelatinous and other areas appearing more firm and fleshy. Focal necrosis is identified (less than 10% of the tumor cut surfaces). A 13.2 x 1.2 x 1.0 cm tubular structure grossly consistent with ureter is identified embedded within and encased by this mass. The ureter is probe patent throughout its length but is grossly distended to maximum diameter of 1.2 cm. Adjacent to the tied off ureter margins several large caliber vessels are identified which appear embedded within the tumor. The margins of the ureter are submitted. The mass is inked black and the specimen is opened to reveal an unremarkable mucosal surface. No mucosal masses or lesions are identified. Lymph nodes are identified in the pericolic adipose tissue and are submitted. Representative sections are submitted. Photographs are taken TPS is submitted.

Summary of sections:

URM -- ureter margins

U -- ureter

M1 -- proximal margin

M2 -- distal margin

VM -- vascular margins

TU -- tumor with adjacent ureter

T1 -- larger tumor

T2 -- smaller tumor

U -- uninvolved mucosa

LN -- lymph nodes

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: Gastric & Mixed Tumo
[REDACTED]

----- Page 3 of 4

2). The specimen is received fresh labeled "left kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 428 g in total. The kidney measures 12.2 x 10.2 x 5.5 cm. The attached ureter measures 2.8 cm in length and 0.7 cm in diameter. The attached renal vein measures 1.5 cm in length and 1.4 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified, measuring 4.9 x 1.7 x 1.5 cm. The kidney is inked black and bivalved to reveal dilated renal pelvis with no renal parenchymal lesions. The capsule of the kidney is focally thickened on the anti-hilar aspect. No grossly evident tumor is identified in this area. The perirenal fat is soft and lobulated. No masses or lesions are identified in the attached soft tissue. The cortex measures 0.8 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted.

Summary of sections:

UVM -- ureteral and vessel margins

RP -- renal pelvis representative sections

K -- representative sections kidney with thickened capsule

PST -- perirenal soft tissues

AD -- adrenal gland

3). The specimen is received in formalin, labeled "iliac vein" and consists of a 2.9 x 1.5 x 1.0 cm fragment of tan -- red soft tissue. The specimen is bisected to reveal a 0.8 x 0.5 x 0.2 cm firm yellow homogeneous nodule. The specimen is entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: SP: Pelvic and left retroperitoneal sarcoma

Block	Sect.	Site	PCs
1		ln	1
1		m1	1
1		m2	1
5		t1	5
3		t2	3
2		tu	2
1		u	1
1		URM	1
1		vm	1

Part 2: SP: Left kidney

** Continued on next page **

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service: Gastric & Mixed Tumo

Page 4 of 4

Block	Sect.	Site	PCs
1		ad	1
1		K	1
3		PST	3
1		RP	2
1		uvm	1

Part 3: SP: Iliac vein

Block	Sect.	Site	PCs
2		u	2

** End of Report **

Source: NCI Genomic Data Commons file 6e9b6bc9-076a-49d1-a0f1-e19dd3048576 (TCGA-DX-A1L1.874C9B81-0181-47D4-95CF-CDB09A6AE5F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).